Gene-level copy-number profile of tumor specimen TCGA-CD-8535-01A from TCGA case TCGA-CD-8535, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 59.0 years (21,559 days).
Specimen TCGA-CD-8535-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.712038e4-9f8c-4988-921a-55beb2f93da9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-8535-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6930f65b-4872-4d3b-8925-218e7051febd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 2,444; copy number 2: 25,069; copy number 3: 22,188; copy number 4: 7,291; copy number 5: 1,226; copy number 6: 1,152; copy number 7: 399; copy number 8: 18; copy number 11: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-8535-01A-11D-2338-01): tumor purity 0.91, ploidy 2.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:45,651,345–46,187,990, 1 gene (within-gene range 0–2): PRKCE.
- chr2:46,003,942–46,078,828, 2 genes: RPL26P15, AC017006.2.
- chr12:12,611,827–12,829,975, 11 genes (within-gene range 0–1): CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,809 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:32,103,445–32,312,987, 8 genes, copy number 5: AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P.
- chr7:70,972–1,269,267, 40 genes, copy number 5: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1.
- chr7:89,882,353–93,361,123, 57 genes, copy number 5 (within-gene range 4–5): STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50.
- chr7:104,894,628–105,115,019, 6 genes, copy number 5 (within-gene range 3–5): LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E.
- chr8:127,578,473–127,636,867, 1 gene, copy number 6: AC104370.1.
- chr9:23,291,544–36,171,334, 260 genes, copy number 5–6 (broad region; genes not listed).
- chr9:112,878,920–113,087,738, 12 genes, copy number 5: SLC46A2, AL139041.1, ZNF883, MUPP, ZNF883, ZFP37, AL162588.1, AL449105.1, AL449105.3, AL449105.4, AL449105.2, AL449105.5.
- chr9:127,867,850–127,906,022, 1 gene, copy number 5 (within-gene range 4–5): AL157935.2.
- chr9:127,885,321–138,203,325, 387 genes, copy number 5 (broad region; genes not listed).
- chr12:52,468,516–52,680,407, 11 genes, copy number 6: KRT6C, KRT6A, KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1.
- chr13:18,467,172–21,878,256, 113 genes, copy number 5 (broad region; genes not listed).
- chr14:40,630,006–42,703,655, 13 genes, copy number 6 (within-gene range 2–6): AL390800.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1, AL442163.2.
- chr16:57,668,277–57,757,244, 5 genes, copy number 5: ADGRG3, AC018552.2, DRC7, AC018552.1, KATNB1.
- chr16:57,759,358–57,772,352, 2 genes, copy number 5: AC092118.2, MIR6772.
- chr17:45,799,390–46,260,606, 13 genes, copy number 6 (within-gene range 3–6): MAPT-AS1, SPPL2C, MAPT, MAPT-IT1, CR936218.2, Metazoa_SRP, STH, KANSL1, CR936218.1, KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2.
- chr19:28,883,430–28,970,874, 1 gene, copy number 5 (within-gene range 4–8): LINC00906.
- chr19:28,949,437–34,355,566, 112 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr19:35,090,930–40,808,434, 318 genes, copy number 7 (broad region; genes not listed).
- chr19:40,808,474–40,826,772, 2 genes, copy number 7: CYP2T1P, CYP2F2P.
- chr20:87,250–13,821,580, 279 genes, copy number 5 (broad region; genes not listed).
- chr20:13,995,369–16,053,197, 1 gene, copy number 5 (within-gene range 4–5): MACROD2.
- chr20:14,884,250–64,313,132, 1,167 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,204. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
